Somatic mutation profile of tumor specimen TCGA-FA-A86F-01A (aliquot TCGA-FA-A86F-01A-11D-A382-10) from TCGA case TCGA-FA-A86F, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 64.7 years (23,641 days).
Specimen TCGA-FA-A86F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cccd144f-436b-4db4-a858-658bfc3d5d6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FA-A86F-10A (Blood Derived Normal), aliquot TCGA-FA-A86F-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94606639-44ac-4eb7-b0ed-367602f4a176

The open-access MAF lists 98 somatic variants for this specimen: 84 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 11, Nonsense Mutation 6, Frame Shift Ins 5, Frame Shift Del 2, Splice Region 2, 3'Flank 2, Nonstop Mutation 1, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66704715; called by muse, mutect2, varscan2
- ABCB5 | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV99329048; called by muse, mutect2, varscan2
- AGTR2 | c.1016G>T p.W339L | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100903599; called by muse, mutect2
- AMBRA1 | c.3860A>G p.D1287G (on ENST00000458649 / NM_001367468.1; = p.D1197G on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100094768; called by muse, mutect2, varscan2
- ANKRD30A | c.3386A>T p.E1129V (on ENST00000611781; = p.E1073V on NM_052997.2) | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100654097; called by muse, mutect2
- CADM1 | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV100523095; called by muse, mutect2
- CADPS2 | c.3031G>C p.D1011H | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100464574; called by muse, mutect2
- CDH11 | c.2157C>A p.D719E | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.05); catalogued as COSV99219273; called by muse, mutect2
- CEP63 | c.1838C>T p.T613I | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs965092900, COSV100132954; called by muse, mutect2
- CHRNA6 | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.417); catalogued as COSV52380009, COSV99373314; called by muse, mutect2, varscan2
- CIITA | c.3134C>A p.S1045Y | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100162381; called by muse, mutect2
- CTNNA3 | c.2026C>A p.Q676K | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs766719017, COSV65523169; called by muse, mutect2, varscan2
- CTSL | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | catalogued as COSV100446715; called by muse, mutect2, varscan2
- CYBB | c.1141A>T p.K381* | Nonsense Mutation (SNP) | VAF 21/175 reads (12%) | catalogued as COSV101059794; called by muse, mutect2, varscan2
- DLX4 | c.611T>C p.L204P (on ENST00000240306 / NM_138281.3; = p.L132P on NM_001934.3) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99537662; called by muse, mutect2, varscan2
- EEF2K | c.1956G>C p.E652D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as COSV99533437; called by muse, varscan2
- EFNB1 | c.311C>A p.P104Q | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99214931; called by muse, mutect2
- ELOVL6 | c.7A>C p.M3L | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100165346; called by muse, mutect2
- ETFRF1 | c.89A>C p.D30A | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100339905; called by muse, mutect2, varscan2
- F7 | c.1081A>G p.N361D | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100661073; called by muse, mutect2, varscan2
- FAT1 | c.8437C>A p.P2813T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as rs1367394395, COSV101499488; called by muse, mutect2, varscan2
- FRMPD3 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs181913680, COSV99346766; called by muse, mutect2
- GPC1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.305); catalogued as rs745441085, COSV50862773; called by muse, mutect2, varscan2
- H2BC5 | c.379T>C p.*127Qext*13 (on ENST00000289316 / NM_138720.2; = p.*127Qext*23 on NM_021063.4) | Nonstop Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as COSV99175312; called by muse, mutect2, varscan2
- HNF4G | c.785T>C p.M262T (on ENST00000354370 / NM_001330561.2; = p.M309T on NM_004133.5) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.782); catalogued as COSV100584809; called by muse, mutect2, varscan2
- HS6ST2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100897291, COSV63712851; called by muse, mutect2
- HSPB2 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 4/69 reads (6%) | catalogued as rs950685918, COSV57051509; called by muse, mutect2
- IDH3B | c.399-2A>G p.X133_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100250246; called by muse, mutect2, varscan2
- INHBA | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99638076; called by muse, mutect2
- INPP5B | c.911C>T p.S304F (on ENST00000373023; = p.S224F on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs952509954, COSV65963348; called by muse, mutect2
- IRS4 | c.1765G>T p.G589W | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as rs1207086440, COSV100929646, COSV64532705; called by muse, mutect2, varscan2
- ITCH | c.194G>A p.W65* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | catalogued as COSV99392692, COSV99392886; called by muse, mutect2
- ITLN1 | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100406289; called by muse, mutect2, varscan2
- KCNN4 | c.538C>G p.R180G | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53456029, COSV99487126; called by muse, mutect2, varscan2
- KIAA1328 | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as COSV99694900; called by muse, mutect2
- KLHDC4 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99566600; called by muse, mutect2
- LRP1B | c.1845G>C p.W615C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101258516; called by muse, mutect2
- LRRC4 | c.950A>G p.E317G | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs745687168, COSV99975130; called by muse, mutect2, varscan2
- MAST4 | c.793T>G p.F265V (on ENST00000403625 / NM_001164664.2; = p.F76V on NM_015183.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs765544422, COSV99845074; called by muse, mutect2, varscan2
- MME | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852468; called by muse, mutect2, varscan2
- MPDZ | c.5746A>T p.I1916F (on ENST00000319217 / NM_001330637.2; = p.I1887F on NM_003829.5) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100057234; called by muse, mutect2
- MPEG1 | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV99915719; called by muse, mutect2
- MPEG1 | c.1820C>T p.T607I | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); catalogued as COSV99915720; called by muse, mutect2, varscan2
- MYOM1 | c.4109G>T p.G1370V | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.287); catalogued as COSV99867653; called by muse, mutect2, varscan2
- NAA25 | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99927841; called by muse, mutect2
- NBAS | c.5117A>G p.E1706G | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99870892; called by muse, mutect2
- NBEA | c.2448C>A p.I816= | Splice Region (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100082467; called by muse, mutect2, varscan2
- NKTR | c.738A>C p.E246D | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV99236074; called by muse, mutect2, varscan2
- NPAS3 | c.2662G>A p.A888T (on ENST00000356141 / NM_001164749.2; = p.A856T on NM_022123.3) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs902489489, COSV100640438; called by muse, mutect2, varscan2
- NPAT | c.1274A>T p.K425I | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99586219; called by muse, mutect2
- NRK | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 8/247 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868566889, COSV99688611; called by muse, mutect2
- NRK | c.891T>A p.N297K | Missense Mutation (SNP) | VAF 10/372 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99688615; called by muse, mutect2
- OR2T34 | c.548dup p.C184Lfs*2 | Frame Shift Ins (INS) | VAF 24/124 reads (19%) | catalogued as rs768006394; called by mutect2, varscan2
- OR4S1 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180298; called by muse, mutect2
- PADI1 | c.1563C>G p.H521Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100969199; called by muse, mutect2
- PCDH17 | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV64972709; called by muse, mutect2, varscan2
- PCSK5 | c.3548G>C p.C1183S | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV101377606; called by muse, mutect2
- PPFIA2 | c.2113A>G p.T705A | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100334511, COSV61033899; called by muse, mutect2
- PRPF31 | c.1149C>A p.I383= | Splice Region (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100320076; called by muse, mutect2, varscan2
- PYY | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63972674; called by muse, mutect2
- RIMS1 | c.3983A>G p.Q1328R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as rs778439163, COSV99328814; called by muse, mutect2, varscan2
- SCN3A | c.4876G>T p.A1626S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99327740; called by muse, mutect2
- SHANK3 | c.4711C>A p.P1571T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99437472; called by muse, mutect2
- SLC5A9 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99361814; called by muse, mutect2
- SLC6A14 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.24); catalogued as COSV100902611; called by muse, mutect2
- SMAD9 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV100614885; called by muse, mutect2, varscan2
- SPEN | c.2653G>T p.E885* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV101005469, COSV65359095, COSV65369507; called by muse, mutect2, varscan2
- STAU1 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.505); catalogued as rs1266481279, COSV100574480; called by muse, mutect2
- TAB3 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99915879; called by muse, mutect2, varscan2
- THEMIS | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.187); catalogued as COSV100965465; called by muse, varscan2
- TLX1 | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV100930089; called by muse, mutect2, varscan2
- TRAM1L1 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.498); catalogued as rs1438967530, COSV60292155; called by muse, mutect2
- UBTF | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs1168315138, COSV57186395; called by muse, mutect2, varscan2
- XRCC2 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100831651; called by muse, mutect2, varscan2
- ZPLD1 | c.55G>T p.A19S (on ENST00000466937 / NM_001329788.1; = p.A35S on NM_175056.2) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100083424; called by muse, mutect2, varscan2
- ARID1A | c.4703del p.P1568Lfs*44 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | called by mutect2, pindel, varscan2
- CTSH | c.587dup p.N196Kfs*7 | Frame Shift Ins (INS) | VAF 10/108 reads (9%) | called by mutect2, varscan2
- E2F1 | c.443_446del p.D148Vfs*5 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel, varscan2
- IGHE | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- IGKV4-1 | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.309); called by muse, mutect2
- KMT2D | c.5834dup p.G1946Rfs*11 | Frame Shift Ins (INS) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- MPEG1 | c.1594_1602del p.F532_C534del | In Frame Del (DEL) | VAF 10/60 reads (17%) | called by pindel, varscan2
- SCN9A | c.5964dup p.*1989Ifs*6 (on ENST00000303354; = p.*1978Ifs*6 on NM_002977.3) | Frame Shift Ins (INS) | VAF 22/238 reads (9%) | called by mutect2, pindel
- SNRNP35 | c.78_85dup p.R29Hfs*21 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- CD36 | c.201C>A p.I67= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV59212551; called by muse, mutect2, varscan2
- CDH3 | c.1065C>T p.D355= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs766592847, COSV50559823; called by muse, mutect2, varscan2
- FRAS1 | c.4212C>G p.T1404= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99354307; called by muse, mutect2
- H2BC21 | c.366C>T p.Y122= | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as COSV58611899; called by muse, mutect2
- IGHV4-34 | c.60T>C p.A20= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs587596498; called by muse, varscan2
- KCTD3 | c.369C>T p.V123= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as COSV99379549; called by muse, mutect2, varscan2
- PIGV | c.612C>T p.S204= | Silent (SNP) | VAF 8/192 reads (4%) | catalogued as COSV50292583; called by muse, mutect2
- PIK3C2G | c.1284T>C p.Y428= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as COSV99852958; called by muse, mutect2
- SORCS3 | c.2028C>T p.S676= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100863708; called by muse, mutect2, varscan2
- TSHZ3 | c.2625C>T p.D875= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs763246396, COSV99552195, COSV99552843; called by muse, mutect2, varscan2
- VIPR2 | c.108A>G p.T36= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as COSV100057798; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81154069 A>C | 3'Flank (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- MIR221 | n.105G>A | RNA (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827953 C>T | 3'Flank (SNP) | VAF 10/274 reads (4%) | catalogued as rs373422817, COSV100158028; called by muse, mutect2
